Somatic mutation profile of tumor specimen TCGA-13-0903-01A (aliquot TCGA-13-0903-01A-01W-0421-09) from TCGA case TCGA-13-0903, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 43.0 years (15,705 days).
Specimen TCGA-13-0903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b12255bd-9ac1-4dea-849a-a22586378c4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0903-10A (Blood Derived Normal), aliquot TCGA-13-0903-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20093480-7238-446f-9151-c5df5f2d78b4

The open-access MAF lists 120 somatic variants for this specimen: 83 protein-altering or splice-affecting, 31 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 31, Nonsense Mutation 4, Splice Site 3, Intron 2, RNA 2, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 116/145 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.588C>G p.D196E | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52535263, COSV52546050; called by muse, mutect2
- ACACB | c.3759G>T p.M1253I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV100623319, COSV58142350; called by muse, mutect2, varscan2
- ARHGAP36 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 152/349 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV52270236; called by muse, mutect2, varscan2
- ARID1B | c.3570G>A p.M1190I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as COSV99270993; called by muse, mutect2, varscan2
- ATAD2B | c.1063A>G p.R355G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs775550833, COSV53203512; called by muse, varscan2
- AZIN2 | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 8/146 reads (5%) | catalogued as COSV99613646; called by muse, mutect2
- CCDC191 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 154/419 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV55674975; called by muse, mutect2, varscan2
- CCDC88B | c.1489G>C p.V497L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs778114059, COSV57267502; called by muse, mutect2, varscan2
- CDC42BPB | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as rs781414650, COSV100775558; called by muse, mutect2, varscan2
- CDYL | c.1048G>A p.D350N (on ENST00000328908 / NM_001368125.1; = p.D296N on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV59359255, COSV59360440; called by muse, mutect2
- CHL1 | c.3347A>T p.K1116M (on ENST00000397491 / NM_001253387.1; = p.K1132M on NM_006614.4) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56601242; called by muse, mutect2, varscan2
- COL11A2 | c.1826G>A p.R609Q (on ENST00000341947 / NM_080680.3; = p.R502Q on NM_080679.2) | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760066546, COSV100554371; called by muse, mutect2
- COL4A4 | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100307426; called by muse, mutect2, varscan2
- CPVL | c.864+2T>G p.X288_splice | Splice Site (SNP) | VAF 99/186 reads (53%) | catalogued as COSV55306292; called by muse, mutect2, varscan2
- DNAH9 | c.11602G>T p.D3868Y | Missense Mutation (SNP) | VAF 84/138 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs1567890901, COSV52332125, COSV52345762; called by muse, mutect2, varscan2
- DOCK6 | c.5894G>A p.R1965Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs766894749, COSV53913545, COSV53919723; called by muse, mutect2, varscan2
- EPHB3 | c.1372A>G p.T458A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.356); catalogued as COSV100383212; called by mutect2, varscan2
- FDXACB1 | c.1131T>A p.F377L | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52790065; called by muse, mutect2, varscan2
- FKBP15 | c.3391T>A p.S1131T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53037986; called by muse, mutect2, varscan2
- FOS | c.733A>C p.N245H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.201); catalogued as COSV57840117; called by muse, mutect2
- FOXA2 | c.519G>T p.Q173H (on ENST00000377115 / NM_153675.3; = p.Q179H on NM_021784.5) | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV65796787; called by muse, mutect2, varscan2
- GOLGB1 | c.8365G>A p.A2789T | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs770543826, COSV61463196; called by muse, mutect2, varscan2
- GTF3C1 | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 107/202 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62243652; called by muse, mutect2, varscan2
- HAPLN1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.354); catalogued as rs191829950; called by mutect2, varscan2
- HDAC3 | c.420+1G>T p.X140_splice | Splice Site (SNP) | VAF 62/158 reads (39%) | catalogued as COSV59497065; called by muse, mutect2, varscan2
- ING5 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.209); catalogued as COSV100546026; called by muse, mutect2
- IQGAP1 | c.2861A>G p.Q954R | Missense Mutation (SNP) | VAF 364/401 reads (91%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV51589257; called by muse, mutect2, varscan2
- ITGAL | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769585343, COSV63323605; called by muse, mutect2, varscan2
- KCMF1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV69054494; called by muse, mutect2, varscan2
- KIF27 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs151248208, COSV99927189; called by muse, mutect2, varscan2
- LARGE1 | c.1410C>G p.D470E | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV61668198; called by muse, mutect2, varscan2
- LIPI | c.1003A>T p.R335W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60714727; called by muse, mutect2, varscan2
- LRRK1 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 23/559 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.316); catalogued as COSV99442050; called by muse, mutect2
- LYST | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 123/321 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV67710715; called by muse, mutect2, varscan2
- MATN2 | c.2282G>A p.R761K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV99646834; called by muse, mutect2
- MERTK | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54931674; called by muse, mutect2
- MFSD2B | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV57855771; called by muse, mutect2, varscan2
- MIER2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs370003436, COSV53395754; called by muse, mutect2, varscan2
- MMP3 | c.190dup p.I64Nfs*33 | Frame Shift Ins (INS) | VAF 21/62 reads (34%) | catalogued as rs782038929; called by mutect2, varscan2
- MMP8 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52633848; called by muse, mutect2, varscan2
- MOCS3 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as COSV54867409, COSV54868232; called by muse, mutect2, varscan2
- MSH4 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 46/177 reads (26%) | catalogued as COSV54208648; called by muse, mutect2, varscan2
- MYH6 | c.2021G>A p.C674Y | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100676852; called by muse, mutect2, varscan2
- MYO5A | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1487252374, COSV62563079; called by muse, mutect2, varscan2
- MYO9B | c.3199G>A p.A1067T | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101261774; called by muse, mutect2
- NOTCH4 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV66681069, COSV66683311; called by muse, mutect2, varscan2
- OPRM1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 88/594 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002048; called by muse, mutect2
- OR2T34 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60901372; called by muse, mutect2, varscan2
- PAPPA2 | c.3058G>T p.V1020L | Missense Mutation (SNP) | VAF 251/538 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs201517784, COSV62806749; called by muse, mutect2, varscan2
- PARP16 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99975604; called by muse, mutect2
- PCDHA3 | c.636A>G p.I212M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV65369886; called by muse, mutect2, varscan2
- PGAP1 | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV61328409; called by muse, mutect2, varscan2
- PLEKHG4B | c.1061C>T p.A354V (on ENST00000283426; = p.A710V on NM_052909.5) | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV99360816; called by muse, mutect2
- PLPPR1 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 23/524 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1324816491, COSV100883426; called by muse, mutect2
- POTEF | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV100665169; called by muse, mutect2, varscan2
- RC3H2 | c.1765T>C p.Y589H | Missense Mutation (SNP) | VAF 374/627 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV61801929; called by muse, mutect2, varscan2
- ROR1 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as COSV64291307; called by muse, mutect2
- RRP12 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.086); catalogued as COSV100213360; called by muse, mutect2, varscan2
- RYR2 | c.11687A>T p.D3896V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63703862; called by muse, mutect2, varscan2
- SDCBP2 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 81/207 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60590399; called by muse, mutect2, varscan2
- SEC23B | c.346A>C p.T116P | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52722683; called by muse, mutect2, varscan2
- SLC23A2 | c.233G>C p.S78T | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV57777734; called by muse, mutect2, varscan2
- SLC35F4 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 49/102 reads (48%) | catalogued as rs766937984, COSV60266301; called by muse, mutect2, varscan2
- SLCO1C1 | c.1490C>A p.T497K | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99859653; called by muse, mutect2, varscan2
- STK11IP | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55247570, COSV55253662; called by muse, mutect2, varscan2
- SZT2 | c.5212C>T p.R1738C (on ENST00000634258 / NM_001365999.1; = p.R1681C on NM_015284.4) | Missense Mutation (SNP) | VAF 199/510 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1443080592, COSV100987551; called by muse, mutect2, varscan2
- TACC1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99393799; called by muse, mutect2
- TBK1 | c.1575A>T p.R525S | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV59157569; called by muse, mutect2, varscan2
- TTLL5 | c.3118C>T p.Q1040* | Nonsense Mutation (SNP) | VAF 39/152 reads (26%) | catalogued as COSV100091178; called by muse, mutect2
- XDH | c.3098C>G p.T1033S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.092); catalogued as rs757665079, COSV65150479; called by muse, mutect2, varscan2
- ZNF174 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.813); catalogued as COSV99237638; called by muse, mutect2
- ZNF174 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs1456597429, COSV99237642; called by muse, mutect2
- ZNF592 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV55438712; called by muse, mutect2, varscan2
- ZP1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99612716; called by muse, mutect2, varscan2
- ATG2B | c.913_924+19del p.X305_splice | Splice Site (DEL) | VAF 27/92 reads (29%) | called by mutect2, pindel, varscan2
- BMP10 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- COBL | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- ICE2 | c.2843C>T p.T948I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, varscan2
- NUP205 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2
- PCK1 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 128/324 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, varscan2
- SBF2 | c.3262G>C p.D1088H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2
- SMC2 | c.3413C>T p.S1138F | Missense Mutation (SNP) | VAF 5/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC6 | c.3042C>G p.A1014= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99229301; called by muse, mutect2
- ALPL | c.450C>T p.I150= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1383812469, COSV100876933; called by muse, mutect2, varscan2
- ANKRD44 | c.2424G>A p.L808= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV56561967; called by muse, mutect2, varscan2
- ARHGEF2 | c.1677G>A p.R559= (on ENST00000361247 / NM_001162383.2; = p.R531= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/69 reads (6%) | catalogued as rs1241200305; called by muse, mutect2
- BTBD9 | c.276C>T p.L92= | Silent (SNP) | VAF 50/572 reads (9%) | called by muse, varscan2
- CACNA2D3 | c.1884C>T p.F628= | Silent (SNP) | VAF 12/266 reads (5%) | catalogued as COSV55540640; called by muse, mutect2
- CYP4F3 | c.240G>A p.L80= | Silent (SNP) | VAF 44/118 reads (37%) | catalogued as COSV55412364; called by muse, mutect2, varscan2
- DAGLA | c.187C>T p.L63= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV99944616; called by muse, mutect2
- EVC2 | c.1102C>T p.L368= | Silent (SNP) | VAF 6/150 reads (4%) | catalogued as rs1429520271; called by muse, mutect2
- EVX2 | c.468G>T p.S156= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV57964581; called by muse, mutect2, varscan2
- FCRL3 | c.2148A>G p.E716= | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as COSV63843850; called by muse, mutect2, varscan2
- FKBP10 | c.951C>A p.I317= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- GRK6 | c.328C>T p.L110= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as rs762693423, COSV100586985; called by muse, mutect2, varscan2
- IGLV2-14 | c.111C>T p.I37= | Silent (SNP) | VAF 14/229 reads (6%) | catalogued as rs748601299; called by muse, mutect2
- ITPR3 | c.405G>A p.V135= | Silent (SNP) | VAF 28/668 reads (4%) | catalogued as COSV100967837; called by muse, mutect2
- LYPD6B | c.99A>C p.S33= (on ENST00000409029 / NM_001317004.1; = p.S57= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/296 reads (7%) | catalogued as COSV99700406; called by muse, mutect2
- MECR | c.876C>T p.P292= | Silent (SNP) | VAF 17/22 reads (77%) | catalogued as rs774083968, COSV55284163, COSV55286889; called by muse, mutect2, varscan2
- MME | c.597C>G p.V199= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as COSV64709330; called by muse, mutect2, varscan2
- MYO10 | c.4689C>T p.T1563= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs780379182, COSV99945967; called by muse, mutect2, varscan2
- P4HB | c.492G>A p.V164= | Silent (SNP) | VAF 14/264 reads (5%) | catalogued as COSV100515894; called by muse, mutect2
- RASSF2 | c.213G>A p.Q71= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as rs1249266732, COSV65082311; called by muse, mutect2
- SATB1 | c.801C>G p.V267= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs764362388, COSV58671722; called by muse, mutect2, varscan2
- SLC6A19 | c.1746G>A p.V582= | Silent (SNP) | VAF 58/322 reads (18%) | catalogued as rs761780267, COSV57253531, COSV99722549; called by muse, mutect2, varscan2
- SLCO1C1 | c.1491A>G p.T497= | Silent (SNP) | VAF 67/159 reads (42%) | catalogued as rs1350700138, COSV56881976; called by muse, mutect2, varscan2
- STK33 | c.1470G>A p.V490= | Silent (SNP) | VAF 160/230 reads (70%) | catalogued as rs769366653, COSV59406698; called by muse, mutect2, varscan2
- STRIP1 | c.306G>A p.E102= | Silent (SNP) | VAF 42/289 reads (15%) | catalogued as COSV100873985; called by muse, varscan2
- TMEM143 | c.9C>T p.V3= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs201886937, COSV99507452; called by mutect2, varscan2
- TRBV24-1 | c.312G>A p.Q104= | Silent (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- UNC5D | c.948A>G p.E316= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV54820864; called by muse, mutect2, varscan2
- ZNF77 | c.888T>C p.Y296= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV100094555, COSV58821888; called by muse, varscan2
- ZP1 | c.540C>T p.P180= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV53924174, COSV99612720; called by muse, mutect2, varscan2
- ABLIM2 | c.1168+1876_1168+1878del | Intron (DEL) | VAF 15/48 reads (31%) | called by pindel, varscan2
- AGAP7P | n.1525T>C | RNA (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2
- ARNT2 | c.*3523C>T | 3'UTR (SNP) | VAF 34/232 reads (15%) | catalogued as rs764320581, COSV57592247; called by muse, mutect2, varscan2
- BPI | c.-1G>A | 5'UTR (SNP) | VAF 12/204 reads (6%) | catalogued as COSV99480873; called by muse, mutect2
- POLR2F | c.453-15066C>T | Intron (SNP) | VAF 74/317 reads (23%) | called by muse, mutect2, varscan2
- SNORD116-2 | n.77C>A | RNA (SNP) | VAF 127/307 reads (41%) | called by muse, mutect2, varscan2
